Surgical pathology report (de-identified scan), TCGA case TCGA-B8-A54E, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-A54E-01A (Primary Tumor).

[page 1 of 4]
ICD0-3

Carcinoma, renal cell, NO
Clear Cell Type 83121.
Site: @ Kidney^{N65} C64.9
"130/12 96"

Diagnosis:

Kidney, right, radical nephrectomy

Histologic tumor type/subtype: renal cell carcinoma,
conventional clear cell type

Sarcomatoid features: not identified

Histologic grade (if applicable): Fuhrman nuclear grade 3 (of 4)

Tumor size (greatest dimension): 6.8 cm by gross examination

Tumor focality: unifocal

Extent of tumor invasion (if present specify if macroscopic or
microscopic):

Capsular invasion/perirenal adipose tissue: negative

Gerota' s fascia: negative

Renal sinus: negative

Major veins (renal vein or segmental branches, IVC): negative

Ureter: negative

Venous (large vessel): negative

Lymphatic (small vessel): negative

Histologic assessment of surgical margins:

Renal parenchymal margin (partial nephrectomy only): not
applicable

Renal capsular margin (partial nephrectomy only): not applicable

Paranephric adipose tissue margin (partial nephrectomy only):
not

applicable

Gerota' s fascia (nephrectomy): negative

Renal vein (nephrectomy): negative

Ureter (nephrectomy): negative

Adrenal gland: not submitted

Lymph nodes: none identified

Other significant findings: incidental angiomyolipoma, 0.17 cm
(A9),

[page 2 of 4]
immunostain confirmatory and positive in scattered cells

AJCC Staging: pT1b pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Comment:

Special stains support the diagnosis. The renal tumor shows positive staining for CD10 with negative staining for E-Cadherin, CD117, RCC and CD15 consistent with renal cell carcinoma, conventional clear cell type. Appropriate controls are performed.

Clinical History:

year-old female with a right renal mass.

Gross Description:

Specimen fixation: Formalin

Type of specimen: Right radical nephrectomy

Side of specimen: Right

Size and weight of specimen: The kidney weighs 260 grams and measures 12.5 x 8.0 x 6.0 cm

Orientation: The external surface of the kidney and perinephric fat is inked blue.

Presence/absence of adrenal gland: Absent

Tumor site: The tumor is within the lower pole of the kidney and involves both the renal cortex and medulla.

Tumor description: The tumor is a fairly well-circumscribed mass with both solid and small cystic components, containing serous fluid. The majority

[page 3 of 4]
of the mass consists of a tan/white solid component with one focal area of hemorrhage identified.

Tumor size: 6.8 x 5.4 x 4.3 cm.

Presence/absence of multicentricity: Absent

Confinement/non-confinement to the kidney: The mass is confined to the kidney and appears to have an intact renal capsule.

Extent of invasion:

Perirenal adipose tissue: Does not involve

Gerota' s fascia: Does not involve

Renal vein: Tumor grossly does not involve

Ureter: Tumor grossly does not involve

Renal Sinus: The tumor is grossly adjacent to the renal sinus focally.

Pelvicaliceal: The tumor focally abuts the renal pelvis.

Adrenal: N/A

Other organs: N/A

Surgical margins:

Perirenal adipose tissue: Negative, tumor is at least 0.3 cm away.

Renal vein: Negative, mass is 3.3 cm away from margin.

Renal artery: Negative, tumor is 3.5 cm away from margin.

Ureter: Negative. The mass is 1.3 cm away from margin.

Description of kidney away from tumor: The remainder of the kidney is tan/pink with distinct cortical and medullary areas. No other masses or lesions are identified.

[page 4 of 4]
Hilar lymph nodes: See block summary.

Other significant findings: None identified

Tissue submitted for special investigations: Tumor and normal are given to tissue procurement.

Digital picture: No

Block Summary:

- A1 - Ureter, vein and artery margins
- A2-A3 - Renal sinus with adjacent tumor
- A4-A5 - Tumor with renal pelvis
- A6-A7 - Tumor with closest blue ink
- A8 - Tumor with normal parenchyma
- A9 - Normal kidney
- A10 - Additional section of tumor and urothelium
- A11 - Two lymph node candidates

HPA Discrepancy		
Discrepancy		
Reviewed		

11/26/12

Source: NCI Genomic Data Commons file ad4b4710-1533-4ab9-bf97-2369e5315fcc (TCGA-B8-A54E.D6DFDD29-822B-40C5-AA22-6B85BF9225E3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).